Somatic mutation profile of tumor specimen MP2PRT-PAPGZW-TMP1-A (aliquot MP2PRT-PAPGZW-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PAPGZW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Precursor B-cell lymphoblastic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (927 days).
Specimen MP2PRT-PAPGZW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbb79de2-a4fa-42df-9cdf-3694fd078413.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPGZW-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPGZW-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f01027d0-c85a-4e6f-8c52-c1857d88191c

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM181A | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 157/486 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373484669; called by muse, varscan2
- SLC5A1 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773674977, COSV56684404; called by muse, mutect2
- LMOD3 | c.1402_1430del p.M468Vfs*6 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2*, pindel
- SCN9A | c.1901_1927del p.R634_G642del | In Frame Del (DEL) | VAF 4/29 reads (14%) | called by mutect2*, pindel
- ADCY1 | c.1692C>T p.R564= | Silent (SNP) | VAF 140/371 reads (38%) | catalogued as rs367735209; called by muse, varscan2
- SHANK1 | c.5391G>T p.L1797= | Silent (SNP) | VAF 178/542 reads (33%) | catalogued as rs1199338269; called by muse, varscan2
